Somatic mutation profile of tumor specimen TCGA-F7-A620-01A (aliquot TCGA-F7-A620-01A-11D-A28R-08) from TCGA case TCGA-F7-A620, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Base of tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G1; Age at diagnosis: 47.8 years (17,475 days).
Specimen TCGA-F7-A620-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a9634a7d-19d8-4dad-82b9-9e68a0a1d999.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F7-A620-10A (Blood Derived Normal), aliquot TCGA-F7-A620-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d281235d-e0f5-415b-b34d-6e9d786e8e01

The open-access MAF lists 68 somatic variants for this specimen: 40 protein-altering or splice-affecting, 23 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 23, Nonsense Mutation 4, RNA 3, In Frame Del 2, Frame Shift Del 2, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 31/96 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as rs28934874, CM012662, CM120847, CM941326, COSV52661698, COSV52676321, COSV52676982, COSV52701855; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANKIB1 | c.2957C>T p.A986V | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV99729215; called by muse, mutect2, varscan2
- APMAP | c.593C>T p.S198F | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.465); catalogued as rs1376907222, COSV99468658; called by muse, mutect2, varscan2
- BAIAP3 | c.292G>T p.G98W | Missense Mutation (SNP) | VAF 23/212 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV100181302; called by muse, mutect2, varscan2
- CDON | c.1823T>C p.I608T | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99701486; called by muse, mutect2, varscan2
- CHRM4 | c.1198C>T p.R400* | Nonsense Mutation (SNP) | VAF 9/86 reads (10%) | catalogued as COSV100551576; called by muse, mutect2
- DIS3 | c.954_956del p.E318del | In Frame Del (DEL) | VAF 20/104 reads (19%) | catalogued as rs745919298; called by pindel, varscan2
- DST | c.4951A>G p.S1651G | Missense Mutation (SNP) | VAF 57/315 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99757077; called by muse, mutect2, varscan2
- ENG | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs747481834, COSV100785301; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- FMN2 | c.4735G>T p.D1579Y | Missense Mutation (SNP) | VAF 33/199 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100145518; called by muse, mutect2, varscan2
- GRAMD1C | c.1585C>G p.Q529E | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as COSV63983232; called by muse, mutect2, varscan2
- HERC1 | c.14236G>A p.E4746K | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV101496618; called by muse, mutect2, varscan2
- HLA-B | c.19C>T p.R7* | Nonsense Mutation (SNP) | VAF 7/44 reads (16%) | catalogued as rs776780353, COSV69520663, COSV69521156; called by muse, mutect2, varscan2
- IL17RD | c.1930C>A p.Q644K | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.006); catalogued as COSV99577356; called by muse, mutect2
- INO80D | c.1457A>G p.K486R | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs772466770, COSV101305850; called by muse, mutect2, varscan2
- KLHDC7A | c.2252G>A p.R751Q | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs772341748, COSV101272794; called by muse, mutect2, varscan2
- KRTAP20-2 | c.74G>C p.G25A | Missense Mutation (SNP) | VAF 12/149 reads (8%) | PolyPhen possibly damaging (0.509); catalogued as COSV58183733; called by muse, mutect2
- MAGI1 | c.2729C>T p.S910L (on ENST00000402939 / NM_001033057.2; = p.S938L on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/210 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.448); catalogued as rs202069482, COSV100441365; called by muse, mutect2, varscan2
- MAPKAP1 | c.1100C>T p.S367L (on ENST00000265960 / NM_001006617.3; = p.S331L on NM_024117.3) | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.053); catalogued as rs1389464216, COSV99785104; called by muse, mutect2, varscan2
- MKI67 | c.6550C>G p.P2184A | Missense Mutation (SNP) | VAF 40/226 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.883); catalogued as COSV100896637; called by muse, mutect2, varscan2
- MTARC1 | c.926G>C p.G309A | Missense Mutation (SNP) | VAF 35/219 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.626); catalogued as COSV100856319, COSV65055303; called by muse, mutect2, varscan2
- NEDD1 | c.1670C>T p.S557F | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV57142634, COSV99901073; called by muse, mutect2, varscan2
- ONECUT1 | c.1190G>A p.R397H | Missense Mutation (SNP) | VAF 27/241 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs200829865, COSV59951103; called by muse, mutect2, varscan2
- PARP14 | c.3404G>A p.G1135E | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101506288; called by muse, mutect2
- PARVB | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs144931273; called by muse, mutect2, varscan2
- PDGFRB | c.2174C>T p.P725L | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV55804698; called by muse, mutect2
- PSG8 | c.80T>A p.F27Y | Missense Mutation (SNP) | VAF 37/213 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as COSV100126307; called by muse, mutect2, varscan2
- PTPRB | c.832C>A p.Q278K | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.094); catalogued as rs1288055998, COSV99717709; called by muse, mutect2, varscan2
- SALL1 | c.751C>T p.R251C | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs772476680, COSV51753884; called by muse, mutect2, varscan2
- SCN1A | c.5690A>G p.N1897S (on ENST00000303395 / NM_001202435.3; = p.N1886S on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1559100116, COSV100320748; called by muse, mutect2, varscan2
- SCUBE3 | c.2552T>C p.L851P | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99234579; called by muse, mutect2, varscan2
- SRGAP3 | c.3035C>A p.P1012H | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.737); catalogued as COSV100841006; called by muse, mutect2, varscan2
- SYNE2 | c.3548A>T p.H1183L | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100647848; called by muse, mutect2, varscan2
- TEP1 | c.7774C>T p.R2592* | Nonsense Mutation (SNP) | VAF 11/72 reads (15%) | catalogued as rs151082585; called by muse, mutect2, varscan2
- TPO | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.56); catalogued as rs575622093, COSV61093745; called by muse, mutect2, varscan2
- TRIP12 | c.5866G>C p.V1956L | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV99390419; called by muse, mutect2, varscan2
- YY1AP1 | c.1765A>T p.K589* (on ENST00000295566 / NM_139118.2; = p.K532* on NM_018253.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 12/212 reads (6%) | catalogued as COSV99804195; called by muse, mutect2
- CST5 | c.305del p.L102Wfs*12 | Frame Shift Del (DEL) | VAF 15/117 reads (13%) | called by mutect2, pindel, varscan2
- KNL1 | c.3432_3433del p.Y1145Ffs*6 (on ENST00000346991 / NM_170589.5; = p.Y1119Ffs*6 on NM_144508.5) | Frame Shift Del (DEL) | VAF 12/84 reads (14%) | called by mutect2, pindel, varscan2
- MYH9 | c.3958_3960del p.E1320del | In Frame Del (DEL) | VAF 20/152 reads (13%) | called by pindel, varscan2
- ADM2 | c.288G>A p.S96= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs779599870, COSV99326939; called by muse, mutect2, varscan2
- ANKS1A | c.3222G>A p.T1074= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as rs367977706; called by muse, mutect2, varscan2
- ASXL3 | c.2208C>G p.L736= | Silent (SNP) | VAF 16/308 reads (5%) | catalogued as COSV99325187; called by muse, mutect2
- B3GNT3 | c.75C>T p.F25= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as COSV100592763; called by muse, mutect2, varscan2
- BHLHE41 | c.363A>G p.K121= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV99658315; called by muse, mutect2
- CAMTA1 | c.1947G>A p.T649= | Silent (SNP) | VAF 60/380 reads (16%) | catalogued as rs374599206; called by muse, mutect2, varscan2
- CARD10 | c.2190G>A p.E730= | Silent (SNP) | VAF 7/85 reads (8%) | catalogued as COSV52654316, COSV52654669; called by muse, mutect2
- CCDC73 | c.2346G>A p.E782= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV100067672; called by muse, mutect2, varscan2
- CHIA | c.1206G>A p.E402= (on ENST00000343320; = p.E294= on NM_021797.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 19/92 reads (21%) | catalogued as rs199879175, COSV100588704; called by muse, mutect2, varscan2
- CRTC1 | c.297G>T p.G99= | Silent (SNP) | VAF 11/161 reads (7%) | catalogued as COSV100119395; called by muse, mutect2
- GFM1 | c.198C>T p.V66= | Silent (SNP) | VAF 9/130 reads (7%) | catalogued as COSV99962937; called by muse, mutect2
- GFRA3 | c.627G>A p.E209= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as COSV99218415; called by muse, mutect2, varscan2
- H4C7 | c.106C>A p.R36= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as rs774688369, COSV55100649, COSV99769120; called by muse, mutect2, varscan2
- ISM1 | c.537G>A p.K179= | Silent (SNP) | VAF 27/127 reads (21%) | catalogued as COSV99339953; called by muse, mutect2, varscan2
- MTTP | c.2166C>T p.G722= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as rs770381109, COSV55511864; called by muse, mutect2
- NEB | c.13437C>A p.P4479= | Silent (SNP) | VAF 3/44 reads (7%) | catalogued as COSV99424118; called by muse, mutect2
- OLFM1 | c.681C>T p.C227= (on ENST00000371793 / NM_001282611.2; = p.C209= on NM_014279.5) | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs746223639, COSV99423954; called by muse, mutect2, varscan2
- SI | c.4239C>T p.D1413= | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as rs138374817; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC45A1 | c.1779C>T p.I593= | Silent (SNP) | VAF 11/105 reads (10%) | catalogued as COSV57100004; called by muse, mutect2, varscan2
- SMARCA2 | c.1503G>A p.E501= | Silent (SNP) | VAF 18/160 reads (11%) | catalogued as COSV100571213; called by muse, mutect2, varscan2
- UGT2B11 | c.645C>T p.I215= | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as rs778846723, COSV101485256; called by muse, mutect2, varscan2
- WDR13 | c.144A>C p.P48= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV99489422; called by muse, mutect2, varscan2
- ZIC3 | c.1017T>C p.F339= | Silent (SNP) | VAF 8/190 reads (4%) | catalogued as COSV99799014; called by muse, mutect2
- AGAP7P | n.1688A>G | RNA (SNP) | VAF 26/306 reads (8%) | called by muse, mutect2
- MAGEA5 | n.154G>T | RNA (SNP) | VAF 17/68 reads (25%) | called by muse, mutect2, varscan2
- PCDHA9 | c.2394+112C>G | Intron (SNP) | VAF 28/234 reads (12%) | catalogued as COSV100969653; called by muse, mutect2, varscan2
- PMS2P3 | n.420G>A | RNA (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2
- SPATA6 | c.-2G>T | 5'UTR (SNP) | VAF 4/23 reads (17%) | catalogued as rs1195621539, COSV100893884; called by muse, mutect2
